Gene-level copy-number profile of tumor specimen TCGA-KM-8639-01A from TCGA case TCGA-KM-8639, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.5 years (24,640 days).
Specimen TCGA-KM-8639-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.1a226646-5071-45eb-b23c-02a81da329cc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KM-8639-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40cb1753-29af-4904-a4f8-764ed9175f98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 52,304; copy number 3: 5,090.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KM-8639-01A-11D-2389-01): tumor purity 0.62, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
